Gene-level copy-number profile of tumor specimen TCGA-IG-A3YC-01A from TCGA case TCGA-IG-A3YC, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 62.4 years (22,774 days).
Specimen TCGA-IG-A3YC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.9c05ef5e-2f9d-457a-bdf3-3ba2fd152ce3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A3YC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/295f441f-c790-4c73-8358-93cfa4a2a55b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 646; copy number 2: 23,010; copy number 3: 22,926; copy number 4: 6,947; copy number 5: 3,655; copy number 6: 1,532; copy number 7: 408; copy number 8: 127; copy number 11: 53; copy number 12: 26; copy number 13: 472; copy number 17: 6; copy number 21: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IG-A3YC-01A-11D-A246-01): tumor purity 0.25, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:34,201,979–34,202,074, 1 gene: Y_RNA.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,094 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:149,517,235–149,736,714, 1 gene, copy number 7 (within-gene range 4–7): WWTR1.
- chr3:149,648,997–150,466,431, 23 genes, copy number 7: WWTR1-IT1, WWTR1-AS1, COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24, AC117386.2, AC022494.1, LINC01998, RPL32P9, AC117386.1, LINC01213, U2, LINC01214, AC018545.1, TSC22D2.
- chr4:185,585,444–185,956,652, 1 gene, copy number 11 (within-gene range 3–21): SORBS2.
- chr4:185,665,885–186,026,586, 5 genes, copy number 11–21: AC108472.1, Y_RNA, AC104805.1, AC096659.1, RNU4-64P.
- chr5:41,730,065–45,895,970, 71 genes, copy number 7 (broad region; genes not listed).
- chr7:89,882,353–109,326,315, 452 genes, copy number 7–17 (broad region; genes not listed).
- chr11:65,487,241–75,594,665, 430 genes, copy number 7–13 (broad region; genes not listed).
- chr19:12,576,100–14,496,149, 111 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 86. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
